Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A1QA, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A1QA-06A (Metastatic).

[page 1 of 2]
***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

(A) LYMPH NODES, RIGHT INGUINAL:

MELANOMA, METASTATIC TO ONE OF TWO LYMPH NODES (1 / 2).

Largest tumor deposit size: 52 x 30 mm (PER GROSS)

Location: INTRAPARENCHYMAL

Extracapsular extension: NOT IDENTIFIED

16D-0-3

Melanoma, NOS 8720/3

Site: lymph node, NOS C77.9

hw 3/15/11

GROSS DESCRIPTION

(A) RIGHT INGUINAL LYMPH NODE, STERILE FOR TIL PROTOCOL AND PANMEL STAINING – One pale gray fibroadipose tissue (9.8 x 4.0 x 2.2 cm) with one dark brown-tan mass (5.2 x 3.0 x 2.5 cm) with dark brown-tan cut surface without hemorrhage or necrosis. Approximately 90% of the specimen is submitted for TIL study and a portion of mass is submitted for melanoma tumor bank. One elongated, firm, pale tan nodule (2.5 x 0.6 x 0.6 cm) is also identified in the adipose tissue with a pale gray cut surface.

SECTION CODE: A1, A2, one cross section of mass; A3, entirely submitted of smaller nodule.

CLINICAL HISTORY

Melanoma.

SNOMED CODES

Some tests reported here may have been developed and performance characteristics determined by Medicine. These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration.*
Entire report and diagnosis completed by:

ADDENDUM

Start of

ADDENDUM

This modified report is being issued to report special studies/IHC/Molecular studies.

COMMENT

Per Dr. request, immunohistochemical stains were performed on paraffin embedded tissue that show that the tumor cells diffusely positive for Mart-1 antibody.

HL/AL Discrepancy		☒

Entire report and diagnosis completed by:

/ MD

[page 2 of 2]
-----END OF REPORT-----

Source: NCI Genomic Data Commons file b03821ce-e0f4-4731-9434-1135549dfdae (TCGA-D3-A1QA.7061E1EB-4CDD-4AB2-A0E5-D84373260890.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).